Somatic mutation profile of tumor specimen MP2PRT-PAUMNF-TBP1-A (aliquot MP2PRT-PAUMNF-TBP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAUMNF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,526 days).
Specimen MP2PRT-PAUMNF-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c488e1e-b2ad-4aea-8b6a-93f79e3aa5c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUMNF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUMNF-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8c3da2a-9aeb-4e2a-8d2b-66e558bd6b80

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 11, Nonsense Mutation 6, 5'Flank 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EHMT1 | c.2408C>G p.S803* | Nonsense Mutation (SNP) | VAF 46/313 reads (15%) | catalogued as rs886042018; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK | c.8059G>C p.E2687Q | Missense Mutation (SNP) | VAF 53/408 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs771493395; called by muse, mutect2, varscan2
- CCDC116 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 40/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53037151; called by muse, mutect2, varscan2
- HEPACAM | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.056); catalogued as rs1254736252, CM1312280; called by muse, mutect2
- MAP3K21 | c.1723C>T p.R575* | Nonsense Mutation (SNP) | VAF 36/366 reads (10%) | catalogued as COSV64041616; called by muse, mutect2
- PCDH15 | c.5833G>A p.E1945K | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.197); catalogued as COSV57402705; called by muse, mutect2, varscan2
- PDE3A | c.2478G>C p.L826F | Missense Mutation (SNP) | VAF 11/383 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62979782; called by muse, mutect2
- TMEM94 | c.3415C>G p.L1139V | Missense Mutation (SNP) | VAF 43/358 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV58600347; called by muse, mutect2, varscan2
- ZNF22 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 52/342 reads (15%) | catalogued as rs1435728082; called by muse, mutect2, varscan2
- ACMSD | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 50/354 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- ART1 | c.370A>C p.N124H | Missense Mutation (SNP) | VAF 74/636 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2
- BACH2 | c.1834G>T p.E612* | Nonsense Mutation (SNP) | VAF 20/163 reads (12%) | called by muse, mutect2, varscan2
- CDC14A | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 13/425 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); called by muse, mutect2
- CEP68 | c.631C>G p.Q211E | Missense Mutation (SNP) | VAF 65/474 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- CSNKA2IP | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2
- CUL9 | c.2161C>A p.R721S | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- F11 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 14/466 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM13B | c.1753G>C p.E585Q | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- INTS3 | c.2643G>A p.M881I | Missense Mutation (SNP) | VAF 85/738 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCND2 | c.604A>T p.N202Y | Missense Mutation (SNP) | VAF 40/404 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- MYO1E | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 42/316 reads (13%) | called by muse, mutect2, varscan2
- NADK2 | c.1044G>C p.L348F (on ENST00000381937 / NM_001085411.3; = p.L185F on NM_153013.4) | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NR3C2 | c.2508T>C p.N836= | Splice Region (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- PARN | c.1720G>C p.E574Q | Missense Mutation (SNP) | VAF 61/495 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PPP4R3C | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PRRC2B | c.6124T>C p.Y2042H | Missense Mutation (SNP) | VAF 53/544 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2
- RYR2 | c.13506G>A p.M4502I | Missense Mutation (SNP) | VAF 11/333 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.096); called by muse, mutect2
- STARD13 | c.1111G>A p.A371T (on ENST00000336934 / NM_001243476.3; = p.A253T on NM_052851.3) | Missense Mutation (SNP) | VAF 44/437 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD6 | c.3544G>C p.E1182Q | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.248); called by muse, mutect2
- TEX15 | c.3070G>A p.E1024K (on ENST00000256246; = p.E1407K on NM_001350162.2) | Missense Mutation (SNP) | VAF 45/310 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNPO1 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 39/470 reads (8%) | called by muse, mutect2
- VPS35L | c.1821G>C p.L607F | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZNF470 | c.817C>G p.Q273E | Missense Mutation (SNP) | VAF 45/411 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- AGO4 | c.1500G>C p.L500= | Silent (SNP) | VAF 43/368 reads (12%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.5787G>A p.V1929= | Silent (SNP) | VAF 47/497 reads (9%) | catalogued as rs1486200051; called by muse, mutect2
- ASAP3 | c.2382C>T p.G794= | Silent (SNP) | VAF 54/390 reads (14%) | called by muse, mutect2, varscan2
- GPS2 | c.855C>A p.L285= | Silent (SNP) | VAF 54/389 reads (14%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.1674G>A p.L558= | Silent (SNP) | VAF 18/508 reads (4%) | called by muse, mutect2
- KCND2 | c.603G>C p.A201= | Silent (SNP) | VAF 40/405 reads (10%) | catalogued as COSV58580870; called by muse, mutect2
- KLHL40 | c.618C>T p.D206= | Silent (SNP) | VAF 30/640 reads (5%) | catalogued as rs867880713, COSV55134100; called by muse, mutect2
- NEK9 | c.2334C>T p.F778= | Silent (SNP) | VAF 57/575 reads (10%) | catalogued as rs1183242841; called by muse, mutect2
- SGO1 | c.1323G>A p.L441= (on ENST00000263753 / NM_001012410.5; = p.L172= on NM_138484.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/238 reads (13%) | catalogued as COSV55425578; called by muse, mutect2, varscan2
- TMEM248 | c.12C>T p.I4= | Silent (SNP) | VAF 32/258 reads (12%) | called by muse, mutect2, varscan2
- ZFHX4 | c.795C>T p.F265= | Silent (SNP) | VAF 16/396 reads (4%) | catalogued as rs934470343, COSV50526666; called by muse, mutect2
- C2orf16 | chr2:27575112 C>T | 5'Flank (SNP) | VAF 39/289 reads (13%) | called by muse, mutect2, varscan2
- DST | c.4297-5010G>A | Intron (SNP) | VAF 25/262 reads (10%) | called by muse, mutect2
